Gene-level copy-number profile of tumor specimen HCM-SANG-1330-C19-01A-01D-A80T-32 from HCMI case HCM-SANG-1330-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; Tumor grade: G2.
Specimen HCM-SANG-1330-C19-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 59fb4a11-13fe-4ddf-b9e9-be6aeaf7d94e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1330-C19-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/52f9c260-fa60-4972-9c86-0b8991ee4232

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 255; copy number 2: 11,334; copy number 3: 28,964; copy number 4: 12,284; copy number 5: 3,337; copy number 6: 1,618; copy number 7: 6; copy number 8: 38; copy number 9: 511; copy number 13: 37.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,370,123–90,683,123, 2 genes (within-gene range 0–2): RN7SKP248, AC093729.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 592 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–91,105, 10 genes, copy number 9: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.3.
- chr11:135,061,781–135,075,908, 1 gene, copy number 7: LINC02684.
- chr13:18,467,172–18,611,675, 5 genes, copy number 7: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388.
- chr13:114,281,601–114,337,626, 4 genes, copy number 9: UPF3A, CLCP2, CHAMP1, LINC01054.
- chr20:23,010,209–25,783,919, 86 genes, copy number 9 (broad region; genes not listed).
- chr20:30,214,765–32,743,567, 78 genes, copy number 8–9 (broad region; genes not listed).
- chr20:33,161,768–35,454,746, 83 genes, copy number 9 (broad region; genes not listed).
- chr20:43,796,437–56,005,519, 274 genes, copy number 8–13 (broad region; genes not listed).
- chr20:57,488,392–59,516,039, 51 genes, copy number 9: HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1, AL389889.1.

Autosomal genes at a single copy (total copy number 1): 255. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
